Somatic mutation profile of tumor specimen MMRF_1786_1_BM_CD138pos (aliquot MMRF_1786_1_BM_CD138pos_T1_KBS5U_L05537) from MMRF case MMRF_1786, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.1 years (17,585 days).
Specimen MMRF_1786_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de64af56-c2ff-4828-9cea-d1bfb9bc8a52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1786_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1786_1_PB_Whole_C3_KBS5U_L05540; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1dab082-4b9f-4478-b3af-aa8bf1170b60

The open-access MAF lists 100 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 25, Intron 16, Silent 10, 3'Flank 7, Nonsense Mutation 4, 5'UTR 4, RNA 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 45/282 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CAMK2A | c.1423G>A p.V475I (on ENST00000348628 / NM_171825.2; = p.V486I on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs771394411; called by mutect2, varscan2
- CGN | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as rs773650342; called by muse, mutect2
- CLMP | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV71650773; called by muse, mutect2, varscan2
- DCHS1 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55044632; called by muse, mutect2
- FOCAD | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 85/422 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747212697, COSV58102053; called by muse, mutect2, varscan2
- FRG2B | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as rs769048271; called by muse, mutect2
- HAPLN4 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 124/215 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52271669; called by muse, mutect2, varscan2
- HIVEP3 | c.6710A>G p.E2237G | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as rs373981666; called by muse, mutect2, varscan2
- IGLV3-1 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs535075254; called by muse, varscan2
- IQGAP3 | c.4082A>G p.N1361S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758207580; called by muse, mutect2, varscan2
- LPL | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 115/211 reads (55%) | catalogued as CM973710; called by muse, mutect2, varscan2
- PPARGC1A | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs767567742, COSV53531266; called by muse, mutect2, varscan2
- RXFP1 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs201584410; called by muse, mutect2, varscan2
- SUN2 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53307042; called by muse, mutect2
- TRIOBP | c.6874G>A p.E2292K (on ENST00000644935 / NM_001039141.3; = p.E579K on NM_007032.5) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs945284342, COSV60378712, COSV60384308; called by muse, mutect2, varscan2
- TSC2 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1287273870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UVSSA | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945790378; called by muse, mutect2, varscan2
- AKT3 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 64/157 reads (41%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.9398G>T p.S3133I (on ENST00000445597; = p.S4141I on NM_001367479.1) | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EYS | c.2567T>G p.L856R | Missense Mutation (SNP) | VAF 113/202 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- IGHV1-18 | c.211_247delinsGCCACTTACAATGGTAACACAAACTATGCACAGAAAT p.S71_L83delinsATYNGNTNYAQKF | Missense Mutation (ONP) | VAF 13/162 reads (8%) | called by muse*, pindel
- LCOR | c.2593A>G p.T865A | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PGBD1 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PLA2R1 | c.4385A>G p.D1462G | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PQBP1 | c.135_136insAG p.E46Rfs*80 | Frame Shift Ins (INS) | VAF 52/109 reads (48%) | called by mutect2, pindel, varscan2
- SCYL1 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- SLCO1B1 | c.854A>T p.K285I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SP140 | c.422C>A p.S141* | Nonsense Mutation (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2, varscan2
- TAB1 | c.667T>C p.L223= | Splice Region (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- TRPM7 | c.2568C>G p.F856L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WDR41 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZKSCAN8 | c.251T>A p.L84* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- ZNF709 | c.1506A>C p.K502N | Missense Mutation (SNP) | VAF 226/360 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP2A1 | c.2580G>A p.E860= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs748129917, COSV62870708; called by muse, mutect2, varscan2
- BTG1 | c.108G>A p.Q36= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs533912735, COSV55457953, COSV55458217, COSV55458575; called by muse, mutect2, varscan2
- CAPN12 | c.255G>A p.P85= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as rs201291255; called by muse, mutect2, varscan2
- IGHD3-16 | c.4T>C p.L2= | Silent (SNP) | VAF 33/33 reads (100%) | catalogued as rs782409863; called by muse, varscan2
- NLE1 | c.123G>A p.P41= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs545024082; called by muse, mutect2, varscan2
- PACSIN3 | c.987G>A p.V329= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- PRR23C | c.147G>T p.A49= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV101356435; called by muse, mutect2, varscan2
- SDR16C5 | c.504C>T p.D168= | Silent (SNP) | VAF 56/123 reads (46%) | catalogued as rs1179031317, COSV58129159; called by muse, mutect2, varscan2
- TAB2 | c.84A>T p.V28= | Silent (SNP) | VAF 65/179 reads (36%) | called by muse, mutect2, varscan2
- ZNF350 | c.1230G>A p.A410= | Silent (SNP) | VAF 75/379 reads (20%) | catalogued as rs371531041; called by muse, mutect2, varscan2
- AC106038.2 | chr8:90703433 A>T | 3'Flank (SNP) | VAF 34/409 reads (8%) | called by muse, mutect2
- ADAD2 | c.*159A>G | 3'UTR (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- ANXA1 | c.-15+2311G>A | Intron (SNP) | VAF 41/440 reads (9%) | called by muse, mutect2
- BMP6 | c.*1072_*1096del | 3'UTR (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel
- C11orf40 | n.244G>A | RNA (SNP) | VAF 70/112 reads (63%) | catalogued as rs1421942523; called by muse, mutect2, varscan2
- CCDC32 | c.*290G>T | 3'UTR (SNP) | VAF 34/251 reads (14%) | called by muse, mutect2, varscan2
- CLPB | c.*60A>G | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- DACT1 | chr14:58647288 G>A | 3'Flank (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- DENND2B | c.-25-25620A>G | Intron (SNP) | VAF 46/230 reads (20%) | called by muse, mutect2, varscan2
- DIO3 | c.*200G>A | 3'UTR (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- DVL2 | c.*51T>C | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- EMX2 | c.-87G>A | 5'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- EPC2 | c.460-22A>G | Intron (SNP) | VAF 83/86 reads (97%) | called by muse, varscan2
- ETS1 | chr11:128460101 C>A | 3'Flank (SNP) | VAF 6/43 reads (14%) | catalogued as rs867931177; called by muse, varscan2
- FAM3C | c.273-75del | Intron (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel
- FLRT2 | chr14:85528776 G>T | 5'Flank (SNP) | VAF 26/62 reads (42%) | called by mutect2, varscan2
- FNIP2 | c.108-19504A>C | Intron (SNP) | VAF 123/281 reads (44%) | called by muse, mutect2, varscan2
- GABRA4 | c.*8943G>A | 3'UTR (SNP) | VAF 16/80 reads (20%) | catalogued as rs900711408; called by muse, mutect2, varscan2
- GDA | c.*3810G>A | 3'UTR (SNP) | VAF 15/73 reads (21%) | catalogued as rs1047111356; called by muse, mutect2, varscan2
- GPD1 | c.*1471A>G | 3'UTR (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
- GSG1 | c.*452G>T | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- GTF2A1 | c.*1076A>T | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- HNF4G | chr8:75566024 TTCCCTTAGAAGACATT>GTTCCCTTAGAAGACATTA | 3'Flank (INS) | VAF 33/110 reads (30%) | called by pindel, varscan2*
- IDE | c.1246-67T>G | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2
- INSYN1 | c.-57C>T | 5'UTR (SNP) | VAF 30/203 reads (15%) | catalogued as rs1485562868; called by muse, mutect2, varscan2
- KIAA0232 | c.*1928_*1931dup | 3'UTR (INS) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- LDHAL6A | c.592+18T>C | Intron (SNP) | VAF 34/152 reads (22%) | catalogued as rs373242445; called by muse, mutect2, varscan2
- LSM3 | c.*1215A>G | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- MORC2 | chr22:30924965 G>C | 3'Flank (SNP) | VAF 61/181 reads (34%) | called by muse, mutect2, varscan2
- MTX3 | c.*609G>A | 3'UTR (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- PDE10A | c.*955T>A | 3'UTR (SNP) | VAF 59/120 reads (49%) | called by muse, mutect2, varscan2
- PIGP | c.*1422_*1428del | 3'UTR (DEL) | VAF 5/72 reads (7%) | called by pindel, varscan2
- PLEKHF2 | c.*1451A>C | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- PPP3CA | c.-294_-271del | 5'UTR (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.*2870C>T | 3'UTR (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- RASAL2 | c.*5260T>G | 3'UTR (SNP) | VAF 43/173 reads (25%) | called by muse, mutect2, varscan2
- RPL37 | c.*3018C>T | 3'UTR (SNP) | VAF 45/230 reads (20%) | catalogued as COSV57038022; called by muse, mutect2, varscan2
- RYR3 | c.3766-60G>A | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- S100A7A | chr1:153421596 G>T | 3'Flank (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- SCAPER | c.3078+67C>T | Intron (SNP) | VAF 6/77 reads (8%) | catalogued as rs1473727313; called by muse, mutect2
- SIRT5 | c.857+4741C>T | Intron (SNP) | VAF 80/164 reads (49%) | catalogued as rs746467087; called by muse, mutect2, varscan2
- SLC26A7 | c.1936-498G>A | Intron (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- SLC5A8 | c.-107C>T | 5'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15971755 G>A | 3'Flank (SNP) | VAF 116/195 reads (59%) | catalogued as rs191595530; called by muse, mutect2, varscan2
- SPTBN1 | c.6420+857C>T | Intron (SNP) | VAF 3/36 reads (8%) | catalogued as rs1231352675; called by muse, mutect2
- TFAP4 | c.823-103C>T | Intron (SNP) | VAF 6/37 reads (16%) | called by mutect2, varscan2
- TGOLN2 | c.*2278del | 3'UTR (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- TIFA | c.*2046G>T | 3'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- TMEM144 | c.*917T>G | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as rs376414090; called by muse, varscan2
- U2SURP | c.1275-631G>A | Intron (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- UBE2H | c.53+3406C>T | Intron (SNP) | VAF 51/184 reads (28%) | called by muse, mutect2, varscan2
- UBE2R2 | c.*60G>T | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- USH1C | c.1284+5367A>G | Intron (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- YES1 | c.*2408C>T | 3'UTR (SNP) | VAF 60/202 reads (30%) | called by mutect2, varscan2
